Somatic mutation profile of tumor specimen MMRF_2068_1_BM_CD138pos (aliquot MMRF_2068_1_BM_CD138pos_T1_KHS5U_L11062) from MMRF case MMRF_2068, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 82.8 years (30,225 days).
Specimen MMRF_2068_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4abc19f7-0715-4fb8-9322-55a43890b52e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2068_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2068_1_PB_WBC_C3_KHS5U_L08803; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/187cb190-631b-4ffc-89d4-c797887966b6

The open-access MAF lists 123 somatic variants for this specimen: 52 protein-altering or splice-affecting, 15 silent, 56 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 45, 3'UTR 28, Silent 15, Intron 14, 5'UTR 8, Frame Shift Del 4, 5'Flank 3, RNA 2, Splice Region 1, Nonsense Mutation 1, 3'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BHLHE22 | c.397G>A p.A133T | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.003); catalogued as rs765899577; called by muse, mutect2, varscan2
- DTHD1 | c.842A>C p.K281T (on ENST00000456874; = p.K116T on NM_001136536.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.321); catalogued as COSV100678405; called by muse, mutect2, varscan2
- ECI2 | c.139A>G p.M47V (on ENST00000380118 / NM_206836.3; = p.M17V on NM_006117.2) | Missense Mutation (SNP) | VAF 88/378 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs142020884, COSV100326393; called by muse, mutect2, varscan2
- FMN1 | c.2609C>T p.P870L (on ENST00000616417 / NM_001277313.2; = p.P647L on NM_001103184.4) | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as rs61740943; called by muse, mutect2, varscan2
- HYDIN | c.1111G>A p.D371N | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55477888; called by muse, mutect2, varscan2
- IGHV2-70 | c.293A>T p.Q98L | Missense Mutation (SNP) | VAF 32/122 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs373048671; called by muse, varscan2
- IGHV2-70 | c.136T>A p.F46I | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.724); catalogued as rs368473747; called by muse, varscan2
- IGHV3-7 | c.35C>G p.A12G | Missense Mutation (SNP) | VAF 88/173 reads (51%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.019); catalogued as rs371532793; called by muse, mutect2, varscan2
- IGLV3-1 | c.148T>G p.Y50D | Missense Mutation (SNP) | VAF 44/136 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.07); catalogued as rs368495152; called by muse, mutect2, varscan2
- LAMA3 | c.1114G>C p.E372Q | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); catalogued as COSV58064627; called by muse, mutect2, varscan2
- MAN2A1 | c.1565A>C p.E522A | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.612); catalogued as COSV54852428; called by muse, mutect2, varscan2
- MED25 | c.34G>A p.G12R | Missense Mutation (SNP) | VAF 27/118 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.361); catalogued as rs753920074; called by muse, mutect2, varscan2
- OCA2 | c.224G>A p.G75E | Missense Mutation (SNP) | VAF 24/164 reads (15%) | SIFT tolerated, low confidence (0.87); PolyPhen benign (0); catalogued as COSV62339231; called by muse, mutect2, varscan2
- PARD3B | c.3266G>A p.G1089E (on ENST00000406610 / NM_001302769.2; = p.G1020E on NM_057177.7) | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1316482866; called by muse, mutect2, varscan2
- POU4F3 | c.859C>G p.R287G | Missense Mutation (SNP) | VAF 19/400 reads (5%) | SIFT tolerated (0.16); PolyPhen probably damaging (1); catalogued as rs1200775614, COSV57942805; called by muse, mutect2
- PPFIA4 | c.533G>A p.R178Q | Missense Mutation (SNP) | VAF 35/119 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55317259; called by muse, mutect2, varscan2
- SCO2 | c.58C>T p.R20W | Missense Mutation (SNP) | VAF 39/141 reads (28%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.075); catalogued as rs771393456; called by muse, mutect2, varscan2
- SHE | c.896G>A p.G299E | Missense Mutation (SNP) | VAF 36/239 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.356); catalogued as rs776441697; called by muse, mutect2, varscan2
- SOX8 | c.544G>A p.G182S | Missense Mutation (SNP) | VAF 61/176 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.581); catalogued as rs1202776187, COSV53508679; called by muse, mutect2, varscan2
- TNFRSF1A | c.1232C>T p.T411M | Missense Mutation (SNP) | VAF 40/131 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0.427); catalogued as COSV50602242; called by muse, mutect2, varscan2
- TPR | c.1725-4A>G | Splice Region (SNP) | VAF 50/188 reads (27%) | catalogued as rs973430523; called by muse, mutect2, varscan2
- WDR87 | c.3308C>T p.T1103M | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0.011); catalogued as rs542731017, COSV58205505; called by muse, mutect2, varscan2
- ZSCAN25 | c.1085A>G p.N362S | Missense Mutation (SNP) | VAF 46/205 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.159); catalogued as rs199783191; called by muse, mutect2, varscan2
- ABCA4 | c.445del p.R149Efs*5 | Frame Shift Del (DEL) | VAF 33/141 reads (23%) | called by mutect2, pindel, varscan2
- ACSF3 | c.632G>T p.G211V | Missense Mutation (SNP) | VAF 4/73 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ARFGAP2 | c.386A>G p.H129R | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- C17orf97 | c.997A>C p.K333Q | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.025); called by muse, varscan2
- CHD7 | c.3103T>C p.F1035L | Missense Mutation (SNP) | VAF 85/427 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- CHMP7 | c.1306G>A p.V436I | Missense Mutation (SNP) | VAF 114/390 reads (29%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- EIF4A1 | c.656A>G p.D219G | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- FAT2 | c.3711C>A p.D1237E | Missense Mutation (SNP) | VAF 54/207 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.526); called by muse, mutect2, varscan2
- FREM2 | c.1783C>A p.L595M | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- GRIK2 | c.1928del p.F643Sfs*13 | Frame Shift Del (DEL) | VAF 21/96 reads (22%) | called by mutect2, pindel, varscan2
- IDO2 | c.14G>C p.R5T (on ENST00000389060; = p.R18T on NM_194294.2) | Missense Mutation (SNP) | VAF 23/146 reads (16%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IFT74 | c.1315G>A p.A439T | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.535); called by muse, mutect2, varscan2
- INO80 | c.1842+2T>A p.X614_splice | Splice Site (SNP) | VAF 20/136 reads (15%) | called by muse, mutect2, varscan2
- KCNS2 | c.1354G>T p.V452F | Missense Mutation (SNP) | VAF 31/175 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- LRFN4 | c.1679C>G p.T560S | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- MEIS2 | c.1087G>A p.G363S (on ENST00000561208 / NM_170675.5; = p.G343S on NM_002399.3) | Missense Mutation (SNP) | VAF 30/130 reads (23%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- NEDD4 | c.754G>A p.V252M | Missense Mutation (SNP) | VAF 37/117 reads (32%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PRICKLE2 | c.126G>A p.W42* | Nonsense Mutation (SNP) | VAF 28/124 reads (23%) | called by muse, mutect2, varscan2
- RAB3GAP1 | c.628G>A p.D210N | Missense Mutation (SNP) | VAF 36/120 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- RBL1 | c.2801A>G p.Y934C | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SBK1 | c.419T>G p.I140S | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- SEC16A | c.4336del p.S1446Qfs*18 | Frame Shift Del (DEL) | VAF 44/242 reads (18%) | called by mutect2, pindel, varscan2
- SLC1A6 | c.262T>C p.Y88H | Missense Mutation (SNP) | VAF 33/115 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); called by muse, mutect2, varscan2
- SSTR5 | c.755T>C p.V252A | Missense Mutation (SNP) | VAF 50/208 reads (24%) | SIFT tolerated (0.38); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- TINAG | c.1068A>T p.R356S | Missense Mutation (SNP) | VAF 60/219 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TRAPPC12 | c.1711G>C p.V571L | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT tolerated (0.82); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- UHRF1BP1 | c.1460del p.K487Sfs*48 | Frame Shift Del (DEL) | VAF 57/264 reads (22%) | called by mutect2, pindel, varscan2
- USP25 | c.2897T>C p.L966S | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- VIL1 | c.974C>T p.P325L | Missense Mutation (SNP) | VAF 36/130 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.249); called by muse, mutect2, varscan2
- ACOX2 | c.1830G>C p.L610= | Silent (SNP) | VAF 14/40 reads (35%) | called by muse, varscan2
- EBF3 | c.1200C>A p.I400= (on ENST00000355311 / NM_001375392.1; = p.I391= on NM_001005463.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 14/45 reads (31%) | catalogued as rs969027167, COSV62472787; called by muse, mutect2
- FFAR2 | c.747A>G p.R249= | Silent (SNP) | VAF 55/185 reads (30%) | catalogued as rs980893837; called by muse, mutect2, varscan2
- IL1RL1 | c.1263G>A p.G421= | Silent (SNP) | VAF 28/111 reads (25%) | catalogued as COSV52114790; called by muse, mutect2, varscan2
- LAMB4 | c.2280C>T p.A760= | Silent (SNP) | VAF 28/139 reads (20%) | catalogued as COSV52726489; called by muse, mutect2, varscan2
- NLRP7 | c.108C>T p.D36= | Silent (SNP) | VAF 49/173 reads (28%) | catalogued as rs1298399106, COSV60175886; called by muse, mutect2, varscan2
- POLM | c.123C>T p.R41= | Silent (SNP) | VAF 39/131 reads (30%) | called by muse, mutect2, varscan2
- PTGER4 | c.225G>A p.V75= | Silent (SNP) | VAF 41/375 reads (11%) | called by muse, mutect2, varscan2
- RBPJ | c.111A>G p.R37= | Silent (SNP) | VAF 31/114 reads (27%) | called by muse, mutect2, varscan2
- SIPA1L3 | c.3162C>T p.Y1054= | Silent (SNP) | VAF 54/246 reads (22%) | catalogued as rs1430340164, COSV55909335; called by muse, mutect2, varscan2
- SLITRK1 | c.1869A>G p.G623= | Silent (SNP) | VAF 48/107 reads (45%) | catalogued as rs777881629; called by muse, mutect2, varscan2
- SOX6 | c.291C>G p.T97= | Silent (SNP) | VAF 65/241 reads (27%) | catalogued as COSV57058982; called by muse, mutect2, varscan2
- TCF7L2 | c.987C>T p.G329= (on ENST00000355995 / NM_001367943.1; = p.G306= on NM_030756.5) | Silent (SNP) | VAF 63/206 reads (31%) | called by muse, mutect2, varscan2
- TIAM1 | c.693C>A p.S231= | Silent (SNP) | VAF 55/230 reads (24%) | catalogued as COSV54561582; called by muse, mutect2, varscan2
- TMEM184C | c.504G>A p.L168= | Silent (SNP) | VAF 21/60 reads (35%) | called by muse, mutect2, varscan2
- ARL14EP | c.*778C>T | 3'UTR (SNP) | VAF 19/56 reads (34%) | called by muse, mutect2, varscan2
- ATF4 | c.-619G>C | 5'UTR (SNP) | VAF 43/132 reads (33%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021407 A>T | 5'Flank (SNP) | VAF 32/118 reads (27%) | catalogued as rs566164810, COSV55850178; called by muse, varscan2
- BCL7A | chr12:122021532 G>T | 5'Flank (SNP) | VAF 38/100 reads (38%) | catalogued as COSV55846310; called by muse, varscan2
- BDNF | c.*2479A>G | 3'UTR (SNP) | VAF 14/110 reads (13%) | called by muse, mutect2, varscan2
- BMP6 | c.*1126T>A | 3'UTR (SNP) | VAF 15/65 reads (23%) | called by muse, mutect2, varscan2
- CALCRL | c.*2430A>T | 3'UTR (SNP) | VAF 39/85 reads (46%) | called by muse, mutect2, varscan2
- CCDC51 | chr3:48440228 del T | 5'Flank (DEL) | VAF 18/107 reads (17%) | called by mutect2, pindel, varscan2
- CFAP20DC | c.1593+1093C>T | Intron (SNP) | VAF 23/75 reads (31%) | called by muse, mutect2, varscan2
- COBLL1 | c.*4134G>A | 3'UTR (SNP) | VAF 20/93 reads (22%) | called by muse, mutect2, varscan2
- CRISP3 | chr6:49728443 A>G | 3'Flank (SNP) | VAF 9/66 reads (14%) | called by muse, mutect2, varscan2
- CSMD3 | c.*1487C>A | 3'UTR (SNP) | VAF 22/106 reads (21%) | called by muse, mutect2, varscan2
- CSRNP3 | c.*8111C>T | 3'UTR (SNP) | VAF 11/47 reads (23%) | called by muse, mutect2, varscan2
- CYP26B1 | c.*2754del | 3'UTR (DEL) | VAF 8/54 reads (15%) | called by mutect2, pindel, varscan2
- DCN | c.211+5934T>C | Intron (SNP) | VAF 25/73 reads (34%) | called by muse, mutect2, varscan2
- DSCR4 | n.481G>T | RNA (SNP) | VAF 10/43 reads (23%) | called by muse, mutect2, varscan2
- EBF1 | c.*2706C>A | 3'UTR (SNP) | VAF 16/92 reads (17%) | called by muse, mutect2, varscan2
- EXOG | c.*564A>G | 3'UTR (SNP) | VAF 26/110 reads (24%) | catalogued as rs548323831; called by muse, mutect2, varscan2
- EYS | c.1767-6617G>A | Intron (SNP) | VAF 55/439 reads (13%) | catalogued as rs757805704; called by muse, mutect2, varscan2
- FAM78A | c.*2092C>T | 3'UTR (SNP) | VAF 32/153 reads (21%) | called by muse, mutect2, varscan2
- FANCE | c.*694del | 3'UTR (DEL) | VAF 18/83 reads (22%) | called by mutect2, pindel, varscan2
- HGF | c.*2281C>T | 3'UTR (SNP) | VAF 33/143 reads (23%) | called by muse, mutect2, varscan2
- HIPK2 | c.*2834_*2842delinsA | 3'UTR (DEL) | VAF 19/83 reads (23%) | called by pindel, varscan2*
- HNRNPKP2 | n.1250G>A | RNA (SNP) | VAF 34/96 reads (35%) | called by muse, mutect2, varscan2
- IGHV1-69D | c.-30A>G | 5'UTR (SNP) | VAF 14/64 reads (22%) | catalogued as rs1190921260; called by muse, varscan2
- INF2 | c.2240-109G>C | Intron (SNP) | VAF 6/25 reads (24%) | called by muse, mutect2, varscan2
- IRF9 | c.649+73A>T | Intron (SNP) | VAF 9/34 reads (26%) | catalogued as rs1186122334; called by muse, mutect2
- ITIH4 | c.1046-19G>T | Intron (SNP) | VAF 34/173 reads (20%) | called by muse, mutect2, varscan2
- KIAA1755 | c.*1189G>T | 3'UTR (SNP) | VAF 24/77 reads (31%) | called by muse, mutect2, varscan2
- LZTR1 | c.*3C>G | 3'UTR (SNP) | VAF 45/170 reads (26%) | called by muse, mutect2, varscan2
- MLEC | c.*1456A>G | 3'UTR (SNP) | VAF 31/80 reads (39%) | catalogued as rs1222260533; called by muse, mutect2, varscan2
- MYT1L | c.*686A>G | 3'UTR (SNP) | VAF 56/367 reads (15%) | called by muse, mutect2, varscan2
- NSMAF | c.149+3011A>T | Intron (SNP) | VAF 23/94 reads (24%) | catalogued as rs1411400196; called by muse, mutect2
- OAZ1 | c.-52_-29del | 5'UTR (DEL) | VAF 9/67 reads (13%) | called by mutect2, pindel, varscan2
- OPN5 | c.*178C>T | 3'UTR (SNP) | VAF 16/101 reads (16%) | called by muse, mutect2, varscan2
- OTUD3 | c.*1972T>A | 3'UTR (SNP) | VAF 16/55 reads (29%) | called by muse, mutect2, varscan2
- PARP15 | c.-13del | 5'UTR (DEL) | VAF 34/191 reads (18%) | called by mutect2, pindel, varscan2
- PCBP2 | c.376-598A>T | Intron (SNP) | VAF 14/26 reads (54%) | called by muse, mutect2, varscan2
- PCDHGC3 | c.2430+143C>T | Intron (SNP) | VAF 36/118 reads (31%) | catalogued as rs1478890031; called by muse, varscan2
- PIWIL4 | c.87+100G>A | Intron (SNP) | VAF 34/117 reads (29%) | catalogued as COSV54409335; called by muse, mutect2, varscan2
- POC1B-GALNT4 | c.*309T>C | 3'UTR (SNP) | VAF 5/105 reads (5%) | called by muse, mutect2
- PSMB4 | c.577-116G>T | Intron (SNP) | VAF 25/143 reads (17%) | called by muse, mutect2
- PTER | c.*1388C>A | 3'UTR (SNP) | VAF 32/102 reads (31%) | catalogued as rs1298753758; called by muse, mutect2, varscan2
- PTK2B | c.2548+434C>T | Intron (SNP) | VAF 9/52 reads (17%) | called by muse, mutect2, varscan2
- RAB26 | c.*187C>G | 3'UTR (SNP) | VAF 110/350 reads (31%) | called by muse, mutect2, varscan2
- SEC14L4 | c.1081+35C>A | Intron (SNP) | VAF 104/313 reads (33%) | called by muse, mutect2, varscan2
- SEL1L | c.*304A>G | 3'UTR (SNP) | VAF 11/44 reads (25%) | called by muse, mutect2, varscan2
- SLC1A2 | c.*4391C>G | 3'UTR (SNP) | VAF 5/74 reads (7%) | called by muse, mutect2
- SPANXN2 | c.-356C>G | 5'UTR (SNP) | VAF 29/66 reads (44%) | called by muse, mutect2, varscan2
- TKFC | c.*1223C>A | 3'UTR (SNP) | VAF 174/452 reads (38%) | called by muse, mutect2, varscan2
- TM9SF2 | c.-86G>A | 5'UTR (SNP) | VAF 74/224 reads (33%) | called by muse, mutect2, varscan2
- TMCO2 | c.*61T>C | 3'UTR (SNP) | VAF 85/312 reads (27%) | called by muse, mutect2, varscan2
- TMEM26 | c.-265G>A | 5'UTR (SNP) | VAF 5/46 reads (11%) | catalogued as rs1033351846; called by muse, mutect2, varscan2
- TRHDE | c.*1488C>T | 3'UTR (SNP) | VAF 15/60 reads (25%) | catalogued as rs945340985; called by muse, mutect2, varscan2
- UCHL3 | c.427-116C>T | Intron (SNP) | VAF 3/9 reads (33%) | called by muse, mutect2
- WDR86 | c.-448C>A | 5'UTR (SNP) | VAF 14/54 reads (26%) | called by mutect2, varscan2
